Somatic mutation profile of tumor specimen C3N-01375-02 (aliquot CPT0088180010) from CPTAC case C3N-01375, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 70.9 years (25,895 days).
Specimen C3N-01375-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44282782-3d43-4528-890b-59a834e882cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01375-31 (Blood Derived Normal), aliquot CPT0088220002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/058f524d-d113-4474-b8a1-d969d158e869

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 4, Frame Shift Del 3, Splice Site 2, RNA 2, In Frame Del 1, Nonsense Mutation 1, Splice Region 1, 3'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 32/302 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DPP7 | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs770245778; called by muse, mutect2
- FGD5 | c.2243G>A p.R748H | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs761640697, COSV53238120; called by muse, mutect2, varscan2
- FRMPD4 | c.2242G>A p.A748T | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); catalogued as COSV66215158; called by muse, mutect2
- HCAR2 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757461993; called by muse, mutect2, varscan2
- HCN1 | c.2486C>T p.A829V | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.04); catalogued as COSV57490881; called by muse, mutect2, varscan2
- HHIP | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56839107; called by muse, mutect2
- KCND1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782327672; called by muse, mutect2, varscan2
- KRT72 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs548680308, COSV53374596; called by muse, mutect2, varscan2
- RBM10 | c.884del p.S295* | Frame Shift Del (DEL) | VAF 26/270 reads (10%) | catalogued as COSV61309921, COSV61313692; called by mutect2, pindel
- SLC22A23 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100978465; called by muse, mutect2
- SPATA18 | c.616C>T p.R206W | Missense Mutation (SNP) | VAF 35/314 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as rs752171868, COSV104401127; called by muse, mutect2, varscan2
- TNFSF11 | c.435G>A p.A145= | Splice Region (SNP) | VAF 50/550 reads (9%) | catalogued as rs775866494, COSV53480184; ClinVar: uncertain significance; called by muse, mutect2
- ACBD5 | c.740A>G p.D247G (on ENST00000375888 / NM_001352568.1; = p.D238G on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/447 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- ANKRD30B | c.1333A>T p.I445F | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); called by muse, mutect2
- ATP11A | c.1175A>G p.E392G | Missense Mutation (SNP) | VAF 40/372 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CANX | c.529-4_529delinsTTTGT p.X177_splice | Splice Site (ONP) | VAF 8/54 reads (15%) | called by mutect2*, pindel
- CNGA2 | c.1062del p.F355Lfs*4 | Frame Shift Del (DEL) | VAF 21/157 reads (13%) | called by mutect2, pindel, varscan2
- EPHX1 | c.831G>C p.R277S | Missense Mutation (SNP) | VAF 77/685 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ETV6 | c.1070T>C p.F357S | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- FAT3 | c.7393T>C p.Y2465H | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2
- GPX2 | c.507del p.Y169* | Frame Shift Del (DEL) | VAF 13/166 reads (8%) | called by mutect2, pindel
- KDM3A | c.3680G>A p.G1227E | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KNL1 | c.1867A>T p.S623C (on ENST00000346991 / NM_170589.5; = p.S597C on NM_144508.5) | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP10 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MAN2A1 | c.1257_1259del p.L420del | In Frame Del (DEL) | VAF 24/260 reads (9%) | called by mutect2, pindel
- PRDM2 | c.2465A>T p.Q822L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSEN1 | c.868+4_868+7del p.X290_splice | Splice Site (DEL) | VAF 27/204 reads (13%) | called by mutect2, pindel, varscan2
- RXRA | c.800A>C p.N267T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TMEM176A | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 13/186 reads (7%) | called by muse, mutect2
- VARS2 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.292); called by muse, mutect2
- WDR45 | c.478G>C p.V160L (on ENST00000376372 / NM_001029896.2; = p.V161L on NM_007075.3) | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- CHD7 | c.2439G>A p.K813= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs1276357189; called by muse, varscan2
- PLEKHG1 | c.1155C>T p.F385= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- SPAG8 | c.1246A>C p.R416= | Silent (SNP) | VAF 20/202 reads (10%) | called by muse, mutect2, varscan2
- SULF2 | c.1824C>T p.N608= | Silent (SNP) | VAF 10/140 reads (7%) | catalogued as COSV63415168; called by muse, mutect2
- LINC02090 | n.264C>G | RNA (SNP) | VAF 12/192 reads (6%) | called by muse, mutect2
- MIR518C | n.89G>A | RNA (SNP) | VAF 15/95 reads (16%) | called by muse, mutect2, varscan2
- NHSL2 | chrX:72144527 G>A | 3'Flank (SNP) | VAF 19/178 reads (11%) | called by muse, mutect2, varscan2
- ZNF410 | c.*422T>A | 3'UTR (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
